Surgical pathology report (de-identified scan), TCGA case TCGA-22-4604, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4604-01A (Primary Tumor).

Surgical Pathology**TISSUE DESCRIPTION:**

Tissue from left upper lobe lung (16.5 x 8.5 x 6.5 cm), separately submitted proximal tracheal margin (2.5 x 1.5 x 1.5 cm), separately submitted bronchial margin of left upper lobe lung (3.5 x 2.8 x 1.1 cm), separately submitted margin left lower lobe lung (1.4 x 0.7 x 0.3 cm), superior mediastinal (left tracheobronchial), aortic (aortopulmonary), inferior (subcarinal) lymph nodes, left lower lobe bronchus lymph node, separately submitted margin left lower lobe lung (1.4 x 0.7 x 0.3 cm)

DIAGNOSIS:

Lung, left upper lobe, lobectomy and sleeve resection: Invasive grade 3 (of 4) squamous cell carcinoma forms a centrally located 4.5 x 3.2 x 3.2 cm mass. The pleura is uninvolved. The proximal tracheal (after re-excision) and distal bronchial margins are negative for tumor. Distal lung segments show post obstructive organizing pneumonia.

Lymph nodes, left upper lobe intrapulmonary peribronchial, excision: Multiple (3 of 8) intrapulmonary peribronchial lymph nodes are involved by metastatic carcinoma.

Lung, separately submitted left lower lobe margin, excision: Lung parenchyma showing organizing pneumonia; negative for tumor.

Lymph nodes, superior and inferior mediastinal, aortic, excision: Multiple superior mediastinal (5 left tracheobronchial), inferior mediastinal (1 subcarinal), aortic (2 aortopulmonary) lymph nodes are negative for tumor.

Lymph nodes, left lower lobe bronchus, excision: Multiple (4) left lower lobe bronchus lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 4cc74de0-15ef-4cd0-84df-465d5d1c667b (TCGA-22-4604.A66769A0-8AD7-4912-8EEE-EC76D5AEF626.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).